Gene-level copy-number profile of tumor specimen TCGA-2H-A9GR-01A from TCGA case TCGA-2H-A9GR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 80.6 years (29,451 days).
Specimen TCGA-2H-A9GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.620c6845-2ab7-40fc-805f-afba14898e17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GR-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b74d3fce-88bd-4e97-9dc6-051a1d66fe46

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 215; copy number 2: 764; copy number 3: 4,861; copy number 4: 16,924; copy number 5: 15,047; copy number 6: 13,883; copy number 7: 3,702; copy number 8: 1,755; copy number 9: 1,393; copy number 10: 666; copy number 11: 86; copy number 12: 92; copy number 13: 44; copy number 14: 98; copy number 15: 28; copy number 16: 64; copy number 17: 9; copy number 20: 30; copy number 22: 45; copy number 32: 15; copy number 36: 5; copy number 40: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GR-01A-12D-A37B-01): tumor purity 0.58, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,663 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:244,352,635–245,709,432, 27 genes, copy number 11: C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2, AC104462.1.
- chr1:246,025,897–246,035,603, 1 gene, copy number 11: AC118555.1.
- chr3:13,816,258–15,971,253, 58 genes, copy number 9: WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P, HMGN2P7, METTL6, EAF1, RNU6-1024P, EAF1-AS1, COLQ, MIR4270, AC027129.1, RN7SL110P, HACL1, BTD, ANKRD28, MIR3134, AC090950.2, AC090950.1, RN7SL4P, AC090945.1, MIR563, IMPDH1P8, AC090946.1.
- chr3:168,666,559–172,427,089, 73 genes, copy number 9 (broad region; genes not listed).
- chr3:175,234,861–176,867,838, 18 genes, copy number 11 (within-gene range 6–11): NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209.
- chr3:186,105,668–190,449,876, 77 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr7:70,972–55,433,742, 942 genes, copy number 9–32 (broad region; genes not listed).
- chr7:78,017,055–79,453,667, 1 gene, copy number 10 (within-gene range 8–10): MAGI2.
- chr7:78,486,530–91,210,590, 116 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:150,584–5,716,804, 75 genes, copy number 9–16 (broad region; genes not listed).
- chr8:6,708,642–8,199,973, 108 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:10,896,045–12,333,693, 65 genes, copy number 16–22 (within-gene range 7–22) (broad region; genes not listed).
- chr8:25,841,725–26,045,413, 1 gene, copy number 11: EBF2.
- chr8:36,764,445–39,105,445, 71 genes, copy number 11–14 (broad region; genes not listed).
- chr8:39,157,538–39,158,701, 1 gene, copy number 14: RPL3P10.
- chr8:63,651,457–65,184,210, 19 genes, copy number 12: AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251.
- chr8:65,714,334–68,331,689, 47 genes, copy number 13–17 (within-gene range 3–17): PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1.
- chr8:69,667,046–71,592,025, 34 genes, copy number 14–17 (within-gene range 5–17): SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2.
- chr8:118,620,498–128,187,101, 163 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr10:42,979,017–56,596,031, 249 genes, copy number 9–13 (broad region; genes not listed).
- chr12:24,566,964–27,972,733, 86 genes, copy number 40 (within-gene range 4–40) (broad region; genes not listed).
- chr12:28,163,298–28,190,738, 2 genes, copy number 40 (within-gene range 4–40): AC022364.1, AC022364.2.
- chr12:69,212,108–70,243,379, 25 genes, copy number 13–20 (within-gene range 4–20): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821.
- chr12:112,570,380–113,966,325, 32 genes, copy number 11: RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1.
- chr12:115,957,905–116,277,693, 1 gene, copy number 36 (within-gene range 4–36): MED13L.
- chr12:116,082,570–116,181,295, 4 genes, copy number 36: RNU6-1188P, MIR620, SNRPGP18, AC130895.1.
- chr13:34,079,411–34,696,612, 8 genes, copy number 9: AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2.
- chr13:59,010,332–60,573,878, 14 genes, copy number 14–20 (within-gene range 3–20): HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3.
- chr15:88,252,730–101,933,350, 345 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
